Somatic mutation profile of tumor specimen TCGA-DM-A1D6-01A (aliquot TCGA-DM-A1D6-01A-21D-A152-10) from TCGA case TCGA-DM-A1D6, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Splenic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DM-A1D6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 174550f0-2b99-4828-8773-6f13167c0b99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1D6-10A (Blood Derived Normal), aliquot TCGA-DM-A1D6-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e8bd5fc-f771-473f-acfe-a93ff6f88d05

The open-access MAF lists 118 somatic variants for this specimen: 81 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 34, Nonsense Mutation 4, Splice Region 2, 3'Flank 2, In Frame Del 1, Intron 1, Frame Shift Ins 1, Frame Shift Del 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3944C>G p.S1315* | Nonsense Mutation (SNP) | VAF 145/165 reads (88%) | hotspot (GDC flag); catalogued as CM021066, CM106373, COSV57326747, COSV57328428, COSV57342242, COSV57397137; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 84/207 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 24/58 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, varscan2
- ABCA10 | c.3901C>G p.H1301D | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52221411; called by muse, mutect2, varscan2
- ABCB11 | c.2825A>T p.E942V | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55589685; called by muse, mutect2, varscan2
- ABCG4 | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 93/108 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1368207364, COSV56643416; called by muse, mutect2, varscan2
- ALDH1A3 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs923605749, COSV60901592; called by muse, mutect2, varscan2
- ALK | c.3513C>A p.I1171= | Splice Region (SNP) | VAF 41/77 reads (53%) | catalogued as COSV66566454, COSV66567946; called by muse, mutect2, varscan2
- ANK2 | c.2929C>T p.R977* | Nonsense Mutation (SNP) | VAF 49/104 reads (47%) | catalogued as COSV100002306, COSV52158715; called by muse, mutect2, varscan2
- ARSG | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV71593070; called by muse, mutect2, varscan2
- AXIN2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61056616, COSV61059970; called by muse, mutect2, varscan2
- BICC1 | c.671A>C p.N224T | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV54063407; called by muse, mutect2, varscan2
- CABP2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 109/133 reads (82%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs768734103, COSV53708793; called by muse, mutect2, varscan2
- CHL1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs575195747, COSV56592321; called by muse, mutect2, varscan2
- CLEC5A | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs140946328; called by muse, mutect2, varscan2
- CSHL1 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs1214104622, COSV51987960; called by muse, mutect2, varscan2
- CX3CL1 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs773596059, COSV50055784; called by muse, mutect2, varscan2
- DCX | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 87/95 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as CM1313995, COSV57568865; called by muse, mutect2, varscan2
- DENND5B | c.2522C>T p.T841M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs750961310, COSV60900062; called by muse, mutect2, varscan2
- DIPK1B | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs767702024, COSV63038015; called by muse, mutect2, varscan2
- DISP1 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52658233; called by muse, mutect2, varscan2
- DOP1A | c.2746C>T p.Q916* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV52709675; called by muse, mutect2, varscan2
- DPEP2 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs150079633, COSV52054459; called by muse, mutect2, varscan2
- ESM1 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV101195643; called by muse, mutect2, varscan2
- EVC2 | c.870G>A p.T290= | Splice Region (SNP) | VAF 67/174 reads (39%) | catalogued as rs768840745, COSV60392781; called by muse, mutect2, varscan2
- F11 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as rs543985619, COSV53006285; called by muse, mutect2, varscan2
- FEZF2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs368222900; called by muse, mutect2, varscan2
- FHOD1 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs373548373; called by muse, mutect2, varscan2
- GABPB1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV55014708; called by muse, mutect2, varscan2
- GPX5 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765613212, COSV69079341; called by muse, mutect2, varscan2
- GRIN2C | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.35); catalogued as COSV53111832; called by muse, mutect2, varscan2
- GZMH | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 213/534 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs200477141, COSV53538152; called by muse, mutect2, varscan2
- HIPK2 | c.96A>C p.K32N | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61227267; called by muse, mutect2, varscan2
- IRX4 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376873295, COSV99180781; called by muse, mutect2, varscan2
- KIF4A | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65542899; called by muse, mutect2, varscan2
- KLHL30 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs767713769, COSV59974978; called by muse, mutect2, varscan2
- KMT2D | c.4474C>T p.Q1492* | Nonsense Mutation (SNP) | VAF 23/41 reads (56%) | catalogued as COSV56435237; called by muse, mutect2, varscan2
- KRT6C | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52877502; called by muse, mutect2, varscan2
- MAP3K10 | c.2808G>A p.M936I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV53422002; called by muse, mutect2, varscan2
- MAPKBP1 | c.4280G>A p.R1427H (on ENST00000456763 / NM_001128608.2; = p.R1421H on NM_014994.3) | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as rs137914592; called by muse, mutect2, varscan2
- MRFAP1L1 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as rs759990042, COSV57923088; called by muse, mutect2, varscan2
- MRPL32 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56239356; called by muse, mutect2, varscan2
- MTNR1B | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs745342258, COSV57066355; called by muse, mutect2, varscan2
- NCKAP5 | c.5506G>A p.G1836R | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs368736527; called by muse, mutect2, varscan2
- NEUROD4 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1208621935, COSV54471402, COSV54474137; called by muse, mutect2, varscan2
- NINL | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs1264826676, COSV54001935; called by muse, mutect2, varscan2
- NOP53 | c.1374-1G>A p.X458_splice | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as COSV55881717; called by muse, mutect2, varscan2
- NTSR2 | c.671_676del p.F224_N226delinsY | In Frame Del (DEL) | VAF 89/246 reads (36%) | catalogued as COSV60990972; called by mutect2, pindel, varscan2
- NXNL1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as rs371790764; called by muse, mutect2, varscan2
- PCDHA4 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV63540711; called by muse, mutect2, varscan2
- PCDHAC2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV99145891; called by muse, mutect2, varscan2
- PPEF2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778475086, COSV54422066; called by muse, mutect2, varscan2
- PRDM1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs771056895, COSV64844950; called by muse, mutect2, varscan2
- PTPRG | c.1578C>G p.I526M | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV55639139; called by muse, mutect2, varscan2
- RAB3C | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51435470; called by muse, mutect2, varscan2
- RNF213 | c.1677T>G p.F559L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV100173380; called by muse, mutect2, varscan2
- RNF216 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 147/246 reads (60%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1339354266, COSV66290265; called by muse, mutect2, varscan2
- RP9 | c.365T>C p.F122S | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV51806848; called by muse, mutect2, varscan2
- SATB2 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV53482909, COSV53486414; called by muse, mutect2, varscan2
- SCRN1 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54130368; called by muse, mutect2, varscan2
- SEC14L2 | c.910A>T p.R304W | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57240933; called by muse, mutect2, varscan2
- SHOX | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV61860731; called by muse, mutect2, varscan2
- SLC25A12 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 96/293 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV55533114; called by muse, mutect2, varscan2
- SLC26A5 | c.1700T>G p.I567S | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV59700995; called by muse, mutect2, varscan2
- SLC5A11 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs776679580, COSV61741365; called by muse, mutect2, varscan2
- SMC2 | c.1545G>C p.K515N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV53957589; called by muse, mutect2
- SMOC1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as rs745832952, COSV62759291; called by muse, mutect2, varscan2
- SPRYD3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 91/240 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs1179055428, COSV56853655; called by muse, mutect2, varscan2
- SPTBN5 | c.8462G>A p.G2821E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.059); catalogued as rs1231249998, COSV58019994; called by muse, mutect2, varscan2
- SRRM2 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs769565277, COSV100070623; called by muse, mutect2, varscan2
- TBX6 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV54221814, COSV54223160; called by muse, mutect2, varscan2
- TIMD4 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV50855044; called by muse, mutect2, varscan2
- TRIM29 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV59280066; called by muse, mutect2, varscan2
- TRPV5 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs779621537, COSV54685314; called by muse, mutect2, varscan2
- YTHDC1 | c.1702C>G p.R568G (on ENST00000344157 / NM_001031732.4; = p.R550G on NM_133370.4) | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV60010246, COSV60012500; called by muse, mutect2, varscan2
- ZNF648 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.276); catalogued as rs1462829731, COSV60570707, COSV60571228; called by muse, mutect2, varscan2
- ZNFX1 | c.5420A>T p.Q1807L | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV65596906; called by muse, mutect2, varscan2
- IGLV3-21 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.229); called by muse, varscan2
- KIAA0895 | c.1068dup p.H357Tfs*2 (on ENST00000297063 / NM_001100425.2; = p.H306Tfs*2 on NM_015314.3) | Frame Shift Ins (INS) | VAF 162/577 reads (28%) | called by mutect2, pindel, varscan2
- TYW1 | c.2180del p.K727Rfs*10 | Frame Shift Del (DEL) | VAF 189/721 reads (26%) | called by mutect2, varscan2
- ABCA2 | c.6504G>A p.A2168= (on ENST00000614293; = p.A2138= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs758812632, COSV55800582; called by muse, mutect2, varscan2
- AOX1 | c.3981A>G p.E1327= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- ATP13A5 | c.2736C>T p.Y912= | Silent (SNP) | VAF 112/252 reads (44%) | catalogued as rs374767252, COSV60868750; called by muse, mutect2, varscan2
- FBXL7 | c.1449C>T p.I483= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs755647091, COSV61645303; called by muse, mutect2, varscan2
- FCN3 | c.312C>T p.S104= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs145351493, COSV99585318; called by muse, mutect2, varscan2
- GCK | c.834C>T p.D278= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs200071687, CM032916, CM097113, COSV60786685; ClinVar: benign; called by muse, mutect2, varscan2
- LIMA1 | c.1947A>G p.G649= | Silent (SNP) | VAF 219/492 reads (45%) | catalogued as COSV57965283; called by muse, mutect2, varscan2
- LMX1B | c.459C>T p.G153= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs779330478, COSV62739376; ClinVar: likely benign; called by muse, mutect2, varscan2
- LMX1B | c.1014G>A p.T338= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs199580468, COSV62738074; called by muse, mutect2, varscan2
- NALCN | c.4578C>T p.G1526= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs780454704, COSV51919160; called by muse, mutect2, varscan2
- NCF2 | c.294G>A p.L98= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV62315264; called by muse, mutect2, varscan2
- NEK9 | c.1521C>T p.G507= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as rs777014945, COSV99463481; called by muse, mutect2, varscan2
- NEUROG3 | c.462G>A p.P154= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs199710370, COSV99653479; called by muse, mutect2, varscan2
- OR4K2 | c.153G>T p.V51= | Silent (SNP) | VAF 50/803 reads (6%) | catalogued as COSV100064362; called by muse, mutect2
- OTOS | c.96G>A p.A32= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs374520622; called by muse, mutect2, varscan2
- PAPLN | c.1905C>T p.H635= (on ENST00000554301; = p.H608= on NM_173462.4) | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs1202311017, COSV53717164; called by muse, mutect2, varscan2
- PCDHA7 | c.1362G>A p.A454= | Silent (SNP) | VAF 74/161 reads (46%) | catalogued as COSV65343734; called by muse, mutect2, varscan2
- PHKB | c.1434C>T p.N478= | Silent (SNP) | VAF 70/164 reads (43%) | catalogued as rs767260379, COSV54520038; called by muse, varscan2
- POM121L12 | c.213G>A p.P71= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs369662403, COSV68692841; called by muse, mutect2, varscan2
- POPDC2 | c.132C>A p.G44= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- PRSS36 | c.120C>T p.R40= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1301508913, COSV51637054; called by muse, mutect2, varscan2
- RAD21 | c.1251C>T p.L417= | Silent (SNP) | VAF 114/145 reads (79%) | catalogued as rs1184536083, COSV52058649; ClinVar: likely benign; called by muse, mutect2, varscan2
- RASA1 | c.1113C>G p.V371= | Silent (SNP) | VAF 116/271 reads (43%) | catalogued as COSV57194972; called by muse, mutect2, varscan2
- ROBO1 | c.1416C>T p.F472= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1248574886, COSV71393968; called by muse, mutect2, varscan2
- RRNAD1 | c.672C>T p.H224= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs766266397, COSV63928927; called by muse, mutect2, varscan2
- SLC2A13 | c.1368G>A p.K456= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV99786345; called by muse, mutect2, varscan2
- SUSD6 | c.489C>T p.V163= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV61365234; called by muse, mutect2, varscan2
- TENM2 | c.6882C>T p.S2294= (on ENST00000518659 / NM_001122679.2; = p.S2055= on NM_001080428.3) | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as rs758474212, COSV69128760; called by muse, mutect2, varscan2
- TLE1 | c.195T>C p.Y65= | Silent (SNP) | VAF 97/211 reads (46%) | catalogued as rs531243540, COSV64686064; called by muse, mutect2, varscan2
- WIF1 | c.1098C>A p.A366= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as rs757666764, COSV54131309; called by muse, mutect2, varscan2
- ZC3H12D | c.498G>A p.P166= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs1464463058, COSV66324256; called by muse, mutect2, varscan2
- ZNF217 | c.1446A>T p.S482= | Silent (SNP) | VAF 217/776 reads (28%) | catalogued as COSV56596565; called by muse, mutect2, varscan2
- ZNF454 | c.465C>T p.S155= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as rs778885859, COSV60768214; called by muse, mutect2, varscan2
- ZNF516 | c.1905G>A p.S635= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs375064691; called by muse, mutect2, varscan2
- LONP2 | chr16:48361715 C>T | 3'Flank (SNP) | VAF 39/89 reads (44%) | catalogued as COSV53522172; called by muse, mutect2, varscan2
- NLRP12 | chr19:53788757 C>T | 3'Flank (SNP) | VAF 59/113 reads (52%) | catalogued as rs769766517; called by muse, mutect2, varscan2
- SMC4 | c.687+271G>T | Intron (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100644009, COSV61005496; called by muse, mutect2
